Somatic mutation profile of tumor specimen ALCH-B532-TTP1-A (aliquot ALCH-B532-TTP1-A-2-0-D-A83F-36) from ALCHEMIST case ALCH-B532, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 21.9 years (8,013 days).
Specimen ALCH-B532-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 31deb9e2-a947-4c9c-bab4-54ebd71c0d6d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B532-NB1-A (Blood Derived Normal), aliquot ALCH-B532-NB1-A-1-0-D-A83F-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/16ec411a-fd34-4331-963a-b67363ee79c6

The open-access MAF lists 51 somatic variants for this specimen: 34 protein-altering or splice-affecting, 11 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 11, Intron 5, Nonsense Mutation 5, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AATF | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs893715982; called by muse, mutect2, varscan2
- ANO1 | c.1664C>T p.S555F | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.56); catalogued as rs1489929108, COSV60290013; called by muse, mutect2
- CASKIN1 | c.3175G>C p.V1059L | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as rs900932823; called by muse, mutect2, varscan2
- CCDC120 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1557080420, COSV100900653; called by muse, mutect2
- FAM161B | c.463G>C p.E155Q (on ENST00000651776; = p.E92Q on NM_152445.3) | Missense Mutation (SNP) | VAF 15/177 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.242); catalogued as COSV53178677, COSV53180332; called by muse, mutect2
- GLIS1 | c.1786G>A p.E596K | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs147342893; called by muse, mutect2, varscan2
- IL17REL | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.811); catalogued as COSV100377487; called by muse, mutect2
- MAP1B | c.2974T>G p.S992A | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as rs1181012930; called by muse, mutect2, varscan2
- MGAM | c.4742C>G p.S1581* | Nonsense Mutation (SNP) | VAF 22/156 reads (14%) | catalogued as COSV72074554; called by muse, mutect2, varscan2
- NAV3 | c.2951C>G p.S984* | Nonsense Mutation (SNP) | VAF 8/138 reads (6%) | catalogued as COSV57058762; called by muse, mutect2
- SPPL3 | c.1139G>A p.R380Q | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1314542418, COSV100793651; called by muse, mutect2, varscan2
- TANC1 | c.4369G>C p.E1457Q | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.007); catalogued as COSV55084205; called by muse, mutect2, varscan2
- TRAPPC9 | c.402C>G p.F134L | Missense Mutation (SNP) | VAF 13/184 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.245); catalogued as COSV101226859; called by muse, mutect2
- TUBGCP3 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1381837456; called by muse, mutect2
- WDR72 | c.115G>T p.G39C | Missense Mutation (SNP) | VAF 34/365 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100854114, COSV100854969, COSV64744006; called by muse, mutect2
- ARID4A | c.3517C>T p.Q1173* | Nonsense Mutation (SNP) | VAF 6/99 reads (6%) | called by muse, mutect2
- CCDC174 | c.89A>C p.K30T | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- CIT | c.3585G>C p.E1195D | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- DSG1 | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 20/195 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPC1 | c.1391+1G>T p.X464_splice | Splice Site (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2
- HCFC1 | c.3919A>T p.T1307S | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- LAMA3 | c.1295A>C p.H432P | Missense Mutation (SNP) | VAF 26/323 reads (8%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.503); called by muse, mutect2
- LARP1 | c.2540C>A p.S847Y (on ENST00000518297 / NM_033551.3; = p.S770Y on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- LPO | c.1505G>C p.R502T | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MGA | c.6859A>T p.K2287* (on ENST00000219905 / NM_001164273.1; = p.K2078* on NM_001080541.2) | Nonsense Mutation (SNP) | VAF 13/100 reads (13%) | called by muse, varscan2
- MSL1 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.497); called by muse, varscan2
- OR2AJ1 | c.887A>C p.D296A | Missense Mutation (SNP) | VAF 9/137 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- PACSIN1 | c.712G>C p.E238Q | Missense Mutation (SNP) | VAF 12/164 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PDIA5 | c.1275G>A p.W425* | Nonsense Mutation (SNP) | VAF 8/127 reads (6%) | called by muse, mutect2
- PKD1 | c.1715C>T p.P572L | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PSG8 | c.330G>C p.Q110H | Missense Mutation (SNP) | VAF 12/316 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.846); called by muse, mutect2
- PWP1 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, mutect2
- RNF113A | c.736G>T p.D246Y | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2
- TRIM56 | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 12/161 reads (7%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); called by muse, mutect2
- ADCY8 | c.2196G>A p.L732= | Silent (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2, varscan2
- ARSH | c.696C>T p.I232= | Silent (SNP) | VAF 24/131 reads (18%) | catalogued as COSV66963903; called by muse, mutect2, varscan2
- ATP5ME | c.30C>T p.L10= | Silent (SNP) | VAF 8/131 reads (6%) | called by muse, mutect2
- DCAF8L1 | c.543C>A p.T181= | Silent (SNP) | VAF 11/103 reads (11%) | catalogued as COSV71595256; called by muse, mutect2, varscan2
- DNAAF2 | c.480C>T p.F160= | Silent (SNP) | VAF 7/94 reads (7%) | catalogued as rs1347268986; called by muse, mutect2
- KRT16 | c.66C>T p.G22= | Silent (SNP) | VAF 24/104 reads (23%) | catalogued as rs570374826, COSV56967227; called by muse, mutect2
- LINS1 | c.1314G>T p.L438= | Silent (SNP) | VAF 58/237 reads (24%) | called by muse, mutect2, varscan2
- RNF5 | c.366C>T p.F122= | Silent (SNP) | VAF 13/327 reads (4%) | called by muse, mutect2
- SALL1 | c.2271T>A p.R757= | Silent (SNP) | VAF 29/274 reads (11%) | called by muse, mutect2
- WIZ | c.1863G>A p.E621= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs1364766940, COSV99653292; called by muse, varscan2
- ZNF699 | c.1134C>T p.L378= | Silent (SNP) | VAF 12/168 reads (7%) | called by muse, mutect2
- COL9A3 | c.1401+14G>A | Intron (SNP) | VAF 36/210 reads (17%) | catalogued as rs374122876; called by muse, mutect2, varscan2
- GSTM5 | c.567+65C>T | Intron (SNP) | VAF 12/226 reads (5%) | called by muse, mutect2
- MARCHF8 | c.242+1054A>G | Intron (SNP) | VAF 8/73 reads (11%) | catalogued as rs752770112; called by muse, mutect2, varscan2
- MIR376A2 | n.35C>T | RNA (SNP) | VAF 4/30 reads (13%) | catalogued as rs371534322; called by mutect2, varscan2
- PCBP2 | c.800-11T>A | Intron (SNP) | VAF 23/117 reads (20%) | called by muse, mutect2, varscan2
- SAT1 | c.202+28G>A | Intron (SNP) | VAF 17/234 reads (7%) | called by muse, mutect2
